Somatic mutation profile of tumor specimen MP2PRT-PANVJV-TMP1-A (aliquot MP2PRT-PANVJV-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANVJV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.0 years (3,297 days).
Specimen MP2PRT-PANVJV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68e6000a-ae1c-404f-8448-772b23c04683.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANVJV-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANVJV-NM1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5111c097-3a4d-42ff-b154-c79623f97e7a

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 14, Silent 4, Splice Site 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 90/413 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- EPS8L2 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 190/739 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as rs1223715606; called by muse, mutect2, varscan2
- EZH2 | c.1703C>T p.T568I (on ENST00000460911 / NM_001203247.2; = p.T573I on NM_004456.5) | Missense Mutation (SNP) | VAF 70/750 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV57452857, COSV57461794; called by muse, mutect2
- ITPR2 | c.6219+1G>T p.X2073_splice | Splice Site (SNP) | VAF 27/114 reads (24%) | catalogued as rs941927094; called by muse, mutect2, varscan2
- MYCBP2 | c.11941A>G p.M3981V (on ENST00000357337; = p.M4019V on NM_015057.5) | Missense Mutation (SNP) | VAF 84/379 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV62010170; called by muse, mutect2, varscan2
- NAV2 | c.2243G>A p.R748Q (on ENST00000396087 / NM_001244963.2; = p.R725Q on NM_145117.5) | Missense Mutation (SNP) | VAF 96/416 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769722553; called by muse, mutect2, varscan2
- OLFML1 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 99/375 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs144878484; called by muse, mutect2, varscan2
- PGPEP1L | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 72/329 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.416); catalogued as rs567611836; called by muse, mutect2, varscan2
- STRA6 | c.1772C>T p.A591V | Missense Mutation (SNP) | VAF 36/696 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs140894233; called by muse, mutect2
- ACTR5 | c.508A>C p.S170R | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.037); called by muse, mutect2
- ATRX | c.6251A>G p.Y2084C | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DNAH5 | c.4439G>T p.C1480F | Missense Mutation (SNP) | VAF 118/411 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- FGFBP2 | c.222C>G p.Y74* | Nonsense Mutation (SNP) | VAF 148/597 reads (25%) | called by muse, mutect2, varscan2
- GIPC3 | c.1295A>T p.Q432L | Missense Mutation (SNP) | VAF 146/531 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- HECA | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 132/468 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KDM5C | c.1533_1534insA p.C512Mfs*5 | Frame Shift Ins (INS) | VAF 125/302 reads (41%) | called by mutect2, pindel, varscan2
- RALGAPB | c.186+3_186+6del p.X62_splice | Splice Site (DEL) | VAF 40/118 reads (34%) | called by pindel, varscan2
- TTLL9 | c.804G>T p.K268N | Missense Mutation (SNP) | VAF 86/525 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ATRX | c.6252C>T p.Y2084= | Silent (SNP) | VAF 56/117 reads (48%) | catalogued as rs1557069206, COSV64881580; called by muse, mutect2, varscan2
- CEACAM18 | c.237C>G p.P79= | Silent (SNP) | VAF 103/432 reads (24%) | called by muse, mutect2, varscan2
- MFSD2A | c.912C>T p.H304= (on ENST00000372809 / NM_001136493.3; = p.H291= on NM_032793.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 75/410 reads (18%) | catalogued as rs201251882; called by muse, mutect2, varscan2
- TMEM259 | c.84C>A p.R28= | Silent (SNP) | VAF 221/922 reads (24%) | called by muse, mutect2, varscan2
